Surgical pathology report (de-identified scan), TCGA case TCGA-24-2038, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2038-01A (Primary Tumor).

[page 1 of 6]
CGA-24-2038

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Address: [REDACTED] Service: [REDACTED] Accession [REDACTED]
Location [REDACTED]
Gender: [REDACTED] MRN: [REDACTED] Taken: [REDACTED]
DOB: [REDACTED] Hospital [REDACTED] Received: [REDACTED]
Patient [REDACTED] Reported: [REDACTED]

Physician(s):
[REDACTED]

Other Related Clinical Data:

DIAGNOSIS:

OVARY, LEFT, SALPINGO-OOPHORECTOMY (INCLUDING FS1)
- SEROUS PAPILLARY NEOPLASM OF LOW MALIGNANT POTENTIAL (SEROUS BORDERLINE TUMOR),
MEASURING 14.5 CM
- CO-EXISTENT MUCINOUS CYSTADENOMA, MEASURING 1.2 CM

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, RIGHT, SALPINGO-OOPHORECTOMY
- SEROUS PAPILLARY CYSTADENOMA OF LOW MALIGNANT POTENTIAL (SEROUS BORDERLINE TUMOR),
MEASURING 5.0 CM

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- CYSTIC ATROPHY

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

SOFT TISSUE, "RECTO-SIGMOID," BIOPSY
- NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, ANTERIOR CUL-DE-SAC, BIOPSY
- NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, LEFT PELVIC SIDEWALL, BIOPSY

[page 2 of 6]
[REDACTED]

[REDACTED]

- NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, LEFT GUTTER, BIOPSY
- NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, POSTERIOR CUL-DE-SAC, BIOPSY
- NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, RIGHT PELVIC SIDEWALL, BIOPSY
- NO EVIDENCE OF MALIGNANCY

SOFT TISSUE, RIGHT GUTTER, BIOPSY
- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, RIGHT PELVIC, EXCISION
- SIX LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/6)

LYMPH NODES, LEFT PELVIC, EXCISION
- EIGHT LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/8)

LYMPH NODES, RIGHT PERIAORTIC, EXCISION
- SIX LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/6)

LYMPH NODES, LEFT PERIAORTIC, EXCISION
- TWO LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/2)

OMENTUM, EXCISION
- NON-INVASIVE DESMOPLASTIC BORDERLINE SEROUS TUMOR IMPLANTS, MULTIPLE

[REDACTED] By this signature, I attest that the above diagnosis is based upon my
personal

examination of the slides (and/or other material indicated in the diagnosis).

Report Electronically Reviewed and Signed Out By [REDACTED].

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pickup fresh LSO - 690-gram ovary measuring 14.5 x 11 x 7 cm with surface excrescences over ~10% of the surface. Opened to show straw-colored fluid and multilocular cysts. Solid papillary tan area measures 5 x 5 x 5 cm. Frozen as FS1. Remainder for permanents," [REDACTED]

FS1: Ovary, left, biopsy
- "Serous tumor of low malignant potential at least," by [REDACTED]

[REDACTED]

Microscopic Description and Comment:

Histologic sections of the left ovary show a serous papillary neoplasm of low malignant potential (serous borderline tumor) that involves the ovarian surface and ovarian parenchyma. An incidental mucinous cystadenoma is identified as well. Sections of the fallopian tube show no histopathologic abnormality. Histologic sections of the separately

[page 3 of 6]
[REDACTED] [REDACTED] [REDACTED]

submitted right ovary show a serous papillary neoplasm of low malignant potential (serous borderline tumor) involving the ovarian surface and parenchyma. Sections of the right fallopian tube show no histopathologic abnormality. There is cystic atrophy of the endometrium. No cervical or myometrial histopathologic abnormalities are identified. Sections of the separately submitted staging biopsies and lymph node dissections show no evidence of metastatic tumor. Routine sections of the omentum show scattered non-invasive desmoplastic implants of serous borderline tumor, with psammoma bodies. [REDACTED]

[REDACTED]

History:

The patient is a [REDACTED] with a complex left ovarian mass. Operative procedure: Examination under anesthesia, laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, and staging with pelvic lymph node dissection.

Specimen(s) Received:

A: OVARY, TUMOR
B: HYSTERECTOMY, RSO UTERUS AND CERVIX
C: RECTAL/SIGMOID COLON
D: ANTERIOR CUL DE SAC
E: LEFT PELVIC SIDEWALL
F: LEFT GUTTER
G: POSTERIOR CUL DE SAC
H: RIGHT PELVIC SIDEWALL
I: RIGHT GUTTER
J: RIGHT PELVIC LYMPH NODES
K: LEFT PELVIC LYMPH NODES
L: RIGHT PERI-AORTIC LYMPH NODES
M: LEFT PERI-AORTIC LYMPH NODES
N: OMENTUM, ROUTINE

Gross Description

The specimens are received in fourteen formalin-filled containers, each labeled with the patient's name. The first container is labeled "LSO, FS1/X" and contains a 690-gram ovary measuring 14.5 x 11.0 x 7.0 cm. There are multiple tan-white papillary excrescences on the ovarian surface covering ~10% of the surface, and measuring 4.0 x 2.5 cm in greatest area. The ovary has been previously opened to reveal a multiloculated cyst with multiple tan-white papillations on the cyst walls. A solid area is present on one side measuring 5.0 x 5.0 x 5.0 cm. Sections show no gross evidence of invasive tumor. A fallopian tube measuring 4.0 cm in length, ranging in diameter from 0.3 to 0.5 cm is present as well. Sections show no discrete tumors. Labeled A1 - tissue previously frozen as FS1; A2 to A14 - sections of cyst including solid areas; A15 to A18 - sections of cyst including external papillary surface excrescences; A19 - fallopian tube. [REDACTED]

The second container is labeled "uterus, cervix, RSO" and contains a 46-gram uterus without adnexa, and a separate ovary and attached fallopian tube. The ovary measures 5.0 x 4.0 x 2.5 cm in greatest dimension and weighs 44 grams. The ovarian surface is covered by multiple tan-white papillary excrescences covering >90% of the ovarian surface. Sections show tan-white papillary structures emanating from the surface of the ovary with no gross evidence of invasion of the underlying ovary. The underlying ovary contains multiple small uniloculated cysts ranging in size from 0.1 to 0.3 cm, filled with clear serous fluid. The remainder of the ovarian parenchyma is firm tan-white. The attached fallopian tube measures 4.0 cm in length and ranges in diameter from 0.4 to 0.7 cm. The serosal surface is smooth and glistening. Sections show no discrete tumors. The serosal surface is tan-brown with focal areas of serosal thickening identified. The uterus measures 7 cm in length x 4.5

[page 4 of 6]
[REDACTED] [REDACTED] [REDACTED]

cm from cornu to cornu x 2.0 cm. The ectocervix is white-tan and smooth. Portions of the ectocervix are not present with the specimen. The area of ectocervix identified measures 1.0 x 0.8 x 0.5 cm and is smooth-white with no discrete lesions identified. The external os measures 0.7 cm in greatest dimension. The endocervical canal measures 2.0 cm in length x 0.4 cm in greatest diameter. The endocervical mucosa is tan with no discrete lesions grossly identified. The endometrial cavity measures 3.3 cm in length x 0.5 cm in greatest width. The endometrial mucosa is tan with no discrete mucosal lesions identified. Sections show no discrete endometrial tumors. Sections through the myometrium show tan myometrium with no discrete tumors identified. Labeled B1 to B6 - right ovary; B7 - right fallopian tube; B8 - anterior cervix; B9 - posterior cervix; B10 - anterior endometrium and myometrium; B11 - posterior endometrium and myometrium; B12 - areas of serosal thickening. [REDACTED]

The third container is labeled "recto-sigmoid biopsy" and contains a single piece of tan-brown soft tissue measuring 3.0 x 2.0 x 0.1 cm. Sections show no discrete lesions. [REDACTED]

The fourth container is labeled "anterior cul-de-sac biopsy" and contains a single piece of firm tan-white tissue measuring 0.5 x 0.3 x 0.2 cm. [REDACTED]

The fifth container is labeled "left pelvic sidewall biopsy" and contains a single piece of tan-brown soft tissue measuring 1.0 x 0.3 x 0.2 cm. [REDACTED]

The sixth container is labeled "left gutter biopsy" and contains a single piece of tan-yellow soft tissue measuring 1.0 x 0.3 x 0.1 cm. [REDACTED]

The seventh container is labeled "posterior cul-de-sac biopsy" and contains a single piece of grey-red soft tissue measuring 0.3 x 0.2 x 0.1 cm. [REDACTED]

The eighth container is labeled "right pelvic sidewall" and contains a single piece of tan-brown soft tissue measuring 0.5 x 0.3 x 0.2 cm. [REDACTED]

The ninth container is labeled "right gutter biopsy" and contains a single piece of tan-brown tissue measuring 0.8 x 0.2 x 0.2 cm. [REDACTED]

The tenth container is labeled "right pelvic lymph node" and contains a single piece of soft lobulated yellow fibroadipose tissue measuring 4.0 x 2.5 x 2.0 cm in greatest dimension. Multiple lymph nodes are dissected from the fibroadipose tissue ranging in size from 0.3 x 0.2 x 0.3 cm to 1.0 x 0.5 x 0.5 cm. Sections of the lymph nodes are homogeneous tan-white lymphoid tissue with no discrete lesions grossly identified. [REDACTED]

The eleventh container is labeled "left pelvic lymph nodes" and contains multiple fragments of soft yellow lobulated fibroadipose tissue ranging in size from 1.4 x 0.5 x 0.3 cm to 3.0 x 2.5 x 2.0 cm. Multiple lymph nodes are dissected from the fibroadipose tissue ranging in size from 0.3 x 0.4 x 0.3 cm to 1.5 x 0.8 x 0.4 cm. Sections of the lymph nodes show homogeneous tan-grey lymphoid tissue with no discrete lesions grossly identified. Labeled K1 and K2. [REDACTED]

The twelfth container is labeled "right periaortic lymph nodes" and contains a single piece of soft lobulated tan-yellow fibroadipose tissue measuring 3.0 x 1.8 x 0.9 cm in greatest dimension. Multiple lymph nodes are dissected from the fibroadipose tissue ranging in size from 0.3 x 0.3 x 0.3 cm to 1.1 x 0.4 x 0.5 cm. [REDACTED]

The thirteenth container is labeled "left periaortic lymph node" and contains a single piece of tan-yellow lobulated fibroadipose tissue measuring 1.5 x 0.5 x 0.8 cm. Two lymph nodes are dissected from the fibroadipose tissue measuring 0.7 x 0.5 x 0.4 cm and 1.0 x 0.5 x 0.4

[page 5 of 6]
[REDACTED]

cm. Sections of both lymph nodes show homogeneous grey-tan lymphoid tissue and no discrete lesions grossly identified. [REDACTED]

The fourteenth container is labeled "omentum" and contains a single portion of omentum measuring 15.5 x 8.0 x 2.0 cm in greatest dimension. The external surface is soft, yellow and lobulated. No discrete lesions identified. Sections show lobulated soft yellow adipose tissue and no discrete lesions or tumor. [REDACTED]

[REDACTED]

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Borderline serous tumor (serous tumor of low grade malignant potential)
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
0 (BORDERLINE TUMOR)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G1 (WELL DIFFERENTIATED)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES NOT invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Tumor DOES NOT invade the pelvic soft tissue.
10. Tumor involvement of the Pelvic peritoneum is ABSENT.
11. Metastaic involvement of the extra-pelvic peritoneum is:
ABSENT
12. Metastaic involvement of the OMENTUM is:
PRESENT; NON-INVASIVE DESMOPLASTIC IMPLANTS
13. The maximum dimension of tumor implants outside the true pelvis is 0.1cm (enter "0" if no implants)
14. Metastatic involvement of the uterine serosa is ABSENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are ABSENT.
17. The total number of regional lymph nodes examined is 22
18. Extranodal extension by tumor is NOT APPLICABLE; no nodal metastases are present
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3a	IIIA	Microscopic peritoneal

implant beyond true pelvis

THE REGIONAL LYMPH NODES are classified as:

N0 (Nodes are free of metastases)

THE STATUS OF DISTANT TUMOR SITES is classified as:

M0 (Distant metastases are reportedly absent)

20. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

IIIA

(T3a/N0/M0)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file b3e82a2a-fc9b-4d14-8bcd-568022d32578 (TCGA-24-2038.82958234-9DE0-429F-8E63-3E8891F1DF81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).